Somatic mutation profile of tumor specimen 0DC29Y from CCDI case PBBLLB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.6 years (6,434 days).
Specimen 0DC29Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fd17c96-deff-4bc2-8262-56e50d336797.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC29N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fb4e180-f189-4362-9e7a-16431ef32183

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCLK3 | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 48/693 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745309621; called by muse, mutect2
- ESCO1 | c.1910A>G p.H637R | Missense Mutation (SNP) | VAF 56/777 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52520106; called by muse, mutect2
- TRIM15 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 38/562 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as rs535327618; called by muse, mutect2
- CYP21A2 | c.495C>G p.F165L | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.251); called by muse, mutect2
- GLO1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 28/500 reads (6%) | called by muse, mutect2
- PCDH18 | c.1182A>T p.E394D | Missense Mutation (SNP) | VAF 83/1050 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2
- MEI1 | c.381G>A p.L127= | Silent (SNP) | VAF 64/576 reads (11%) | catalogued as COSV55902405; called by muse, mutect2, varscan2
- NLRP1 | c.3243C>T p.G1081= | Silent (SNP) | VAF 32/546 reads (6%) | called by muse, mutect2
- SLITRK6 | c.2247C>T p.F749= | Silent (SNP) | VAF 68/1400 reads (5%) | called by muse, mutect2
- UTRN | c.5619G>A p.L1873= | Silent (SNP) | VAF 46/1060 reads (4%) | called by muse, mutect2
